Somatic mutation profile of tumor specimen TARGET-10-PARBHI-09A (aliquot TARGET-10-PARBHI-09A-01D) from TARGET case TARGET-10-PARBHI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,248 days).
Specimen TARGET-10-PARBHI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce372947-ed45-4f3d-bcb8-19b6997623e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBHI-10A (Blood Derived Normal), aliquot TARGET-10-PARBHI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6720044-6283-4cb8-b5ba-e827a24b5f5f

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 4, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAP2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs778195436; called by muse, mutect2, varscan2
- ETV6 | c.313_314insAATC p.R105Qfs*8 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | catalogued as COSV67154145; called by mutect2, pindel
- MCF2L | c.2752G>A p.A918T (on ENST00000375608; = p.A886T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs201538160, COSV56176175; called by muse, mutect2, varscan2
- RASSF6 | c.916G>T p.A306S (on ENST00000342081 / NM_201431.2; = p.A274S on NM_177532.5) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.266); catalogued as COSV100274801; called by muse, mutect2
- UMOD | c.865+1G>T p.X289_splice | Splice Site (SNP) | VAF 3/21 reads (14%) | catalogued as rs975142603; called by muse, mutect2
- ALG2 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); called by muse, mutect2
- CA14 | c.238C>A p.H80N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CDK12 | c.3269C>A p.A1090D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2
- MMP14 | c.1299C>A p.N433K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.312); called by muse, mutect2
- MYEF2 | c.671G>T p.S224I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2
- NTNG2 | c.384C>A p.N128K | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SERPINB4 | c.457A>C p.S153R | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SULT1E1 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- THRAP3 | c.1268C>A p.A423D | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2
- VCAN | c.3881C>A p.P1294H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2
- CCNT1 | c.2001G>T p.L667= | Silent (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- MROH7 | c.1032G>A p.L344= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs376456399; called by muse, mutect2, varscan2
- PEX10 | c.682C>T p.L228= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- PITRM1 | c.1542G>A p.Q514= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- AL645929.2 | chr6:29888586 C>A | 5'Flank (SNP) | VAF 14/74 reads (19%) | catalogued as rs768398557; called by muse, varscan2
- CSMD3 | c.401+35A>C | Intron (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- DYSF | c.458-474G>A | Intron (SNP) | VAF 31/76 reads (41%) | catalogued as rs867037196, COSV50279440; called by muse, mutect2
- MED6 | c.357+24G>T | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs754195396; called by mutect2, varscan2
- SLC41A3 | c.1366+87G>T | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
